Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACF-01A (Primary Tumor).

[page 1 of 3]
UUID: S7E9FFF8-F926-4793-AF09-691BDA2248C9

CLINICAL DIAGNOSIS: HCC (S4)

Specimen : liver

Gross Photo :

GROSS:

1. Specimen:

Liver: 11.5 x 6.8 x 6.2 cm, 208.5 gm, unfixed

Gallbladder:

11.0 cm in length, 4.5 cm in diameter, and 0.4 cm in thickness, unfixed
with cystic lymph node (1.2 x 1.0 x 0.8 cm)

2. Tumor location: segment 4

Tumor number: one

Tumor size: 4.4 x 3.4 x 3.0 cm

Distance to resection margin: 0.2 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: no

6. Hemorrhage/peliosis: yes (50 %)

7. Portal vein invasion: no

8. Bile duct invasion: no

Gross photo present.

Blocks x 9

T1-4 and TB, tumor mass x 5

RM, resection margin x 1

L and NB, non-tumorous liver parenchyme x 2

GB, gallbladder x 1

LN, cystic lymph node x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation II

1-2. Histologic type: pseudoglandular

1-3. Cell type: hepatic

1-4. Fatty change: < 5 %

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
JPS 5/19/14

[page 2 of 3]
- 2. Cholangiocarcinoma: no
- 3. Combined hepatocellular and cholangiocarcinoma: no
- 4. Fibrous capsule formation: partial capsule
- 5. Capsular infiltration: yes
- 6. Septum formation: no
- 7. Surgical resection margin invasion: no, margin of the clearance (0.2 cm)
- 8. Serosal invasion: no
- 9. Portal vein invasion: no
- 10. Bile duct invasion: no
- 11. Hepatic vein invasion: no
- 12. Hepatic artery invasion: no
- 13. Microvessel invasion: no
- 14. Intrahepatic metastasis: no
- 15. Multicentric occurrence: no

Non-tumor liver pathology

- 1. Chronic hepatitis: yes
- 1-1. Etiology: HCV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
- 2. Dysplastic nodule: no
- 3. Ductal epithelial dysplasia: no
- 4. Other liver diseases: no

NOT reported. Gross:

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, steatosis, cirrhosis
T56000, P10, M81703, M50080, M49500
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005
Lymph node, cystic, ectomy, reactive hyperplasia
T08000, cystic, P10, M72200

DIAGNOSIS:

Liver, segment 4, central hepatectomy:
Hepatocellular carcinoma, moderately differentiated

[page 3 of 3]
Steatosis, mild
Cirrhosis, micronodular
Gallbladder, cholecystectomy:
Chronic cholecystitis
Lymph node, cystic, cholecystectomy:
Reactive hyperplasia

Suggestion :

Source: NCI Genomic Data Commons file 8acf7760-01a6-483c-810a-85f445a2758c (TCGA-DD-AACF.57E9FFF0-F926-4793-AF09-691BDA2248C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).